Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61I, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61I-01A (Primary Tumor).

[page 1 of 6]
PATIENT:

AGE/SEX: /M

REG DR:

Received:
Copies to:

Collected:

SPECIMEN ID:

- A. MUSCLE - DEEP MUSCLE INFERIOR MARGIN FS,
- B. PALATE, NOS - LEFT SUPERIOR SOFT PALATE MARGIN FS,
- C. MOUTH - RETROMOLAR MUCOSA MARGIN FS, D. TONGUE - DEEP TONGUE MARGIN FS,
- E. UVULA PALATINA - UVULA FS, F. TONSIL - LEFT RADICAL TONSILLECTOMY,
- G. NECK, NOS - LEFT NECK DISSECTION, H. LYMPH NODE - LEVEL 2B LYMPH NODE,
- I. LYMPH NODE - LEVEL 5B LYMPH NODE

A. DEEP MUSCLE INFERIOR MARGIN:

No carcinoma seen.

B. LEFT SUPERIOR SOFT PALATE MARGIN:

No carcinoma seen.

C. RETROMOLAR MUCOSA MARGIN:

No carcinoma seen.

D. DEEP TONGUE MARGIN:

No carcinoma seen.

E. UVULA:

No carcinoma seen.

ICD-O-3
Carcinoma, squamous cell
non-keratinizing NOS 8072/3
Site @ Tonsil NOS 809.9
JW 5/14/13

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 2 of 6]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

F. LEFT RADICAL TONSILLECTOMY:

INVASIVE, POORLY DIFFERENTIATED, NON-KERATINIZING SQUAMOUS CELL CARCINOMA, 1.8 cm in greatest dimension.

Margins are free of carcinoma.

No perineural invasion seen.

Lymphovascular invasion is identified.

AJCC pT1 N2b Mx/a

See Tumor Summary

By immunohistochemistry, tumor cells are positive for keratin (strong cytoplasmic), CK5/6, p63, and negative for HLA-DR. They are positive for diffuse cytoplasmic and focal nuclear staining for p16. HPV testing by in situ hybridization is underway.

G. LEFT NECK DISSECTION:

METASTATIC CARCINOMA to two of thirty-two lymph nodes (2/32).

Largest metastatic focus measures 4.5 cm and may represent metastatic carcinoma to a conglomerate of matted lymph nodes.

Although metastatic carcinoma focally approaches lymph node capsule, no definitive extranodal extension is identified.

Salivary gland with chronic sialadenitis.

H. LEVEL 2B LYMPH NODE:

METASTATIC CARCINOMA to one of five lymph nodes (1/5).

No extranodal extension seen.

I. LEVEL 5B LYMPH NODE:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 3 of 6]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Four lymph nodes, no carcinoma seen (0/4).

Surgical Pathology Cancer Case Summary

Specimen: Left radical tonsillectomy and pharyngectomy

Received: In formalin

Procedure: Resection

Tonsillectomy

Pharyngectomy

Neck (lymph node) dissection: left

Specimen Integrity: Intact

Specimen Size: Greatest dimensions: 4.5 x 3.8 x 1.5 cm

Specimen Laterality: Left

Tumor Site: Oropharynx

Tumor Laterality: Left

Tumor Size:

Greatest dimension: 1.8 cm

Additional dimensions: 1.5 x 1.3 cm

Histologic Type: Squamous cell carcinoma, conventional

Histologic Grade: G3: Poorly differentiated

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Present

Perineural Invasion: Not identified

Lymph Nodes, Extranodal Extension: Not identified

Pathologic Staging (pTNM):

Primary Tumor (pT):

pT1: Tumor 2 cm or less in greatest dimension

Regional Lymph Nodes (pN):

pN2b: Metastasis in multiple ipsilateral lymph nodes, non more than 6 cm in greatest dimension

Number examined: 41

Number involved: 3

Distant Metastasis (pM):

Not applicable

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 4 of 6]
(Continued)

CLINICAL HISTORY-

PRE-OP DX: Not provided

PROCEDURE: Left radical tonsillectomy and pharyngectomy

RELEVANT CLINICAL HX: The patient has history of left tonsil cancer.

GROSS DESCRIPTION:

- A. Received fresh and labeled "Deep muscle margin inferior" is an irregular-shaped red-tan soft tissue fragment, 1.3 x 0.8 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- B. Received fresh and labeled "Left superior soft palate margin" is a red-tan soft tissue fragment, 1.4 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- C. Received fresh and labeled "Retromolar mucosa margin" is a pink-tan soft tissue fragment, 1.7 x 0.8 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- D. Received fresh and labeled "Deep tongue margin" is a pink-tan soft tissue fragment, 1.8 x 1.0 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- E. Received fresh and labeled "Uvula" is a pink-tan soft tissue fragment, 0.5 x 0.4 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- F. Received in formalin and labeled "Left radical tonsillectomy and left pharyngectomy" is an irregular-shaped, pink-tan soft tissue fragment with overlying mucosa, 4.5 x 3.8 x 1.5 cm. The specimen was oriented at the frozen section room, as follows: superior surgical resection margin inked yellow, inferior surgical resection margin inked blue, medial surgical resection margin inked red, lateral surgical resection margin inked green and deep surgical resection margin inked black. The specimen is serially sectioned and reveals an ill-circumscribed, white firm tumor arising from the tonsil, which invades into the adjacent soft tissue, 1.8 x 1.5 x 1.3 cm. The tumor is 0.2 cm within the deep surgical resection margin (nearest), 0.3 cm from the superior surgical resection margin, 0.6 cm from the inferior surgical resection margin, 1.0 cm from the medial surgical resection margin and 0.4 cm from the lateral surgical resection margin. The specimen is submitted as follows:

Cassette #1:	Perpendicular superior margin
Cassette #2:	Perpendicular inferior margin
Cassette #3:	Perpendicular medial margin
Cassette #4&5:	Composite section of the tumor in relation with lateral, deep and inferior margin (cassette #4: lateral margin)
Cassette #6&7:	Additional section of tumor in relation with deep surgical

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 5 of 6]
(Continued)

GROSS DESCRIPTION: (Continued)

margin

Note: There was a 0.4 cm portion of tumor sent fresh to Tissue Bank.

- G. Received in formalin and labeled "Left neck dissection, level IB, IIA, III and IV" is an unoriented irregular-shaped, yellow-tan fibroadipose tissue fragment, 15.0 x 8.0 x 3.5 cm. In the same container, there are four irregular-shaped, yellow-tan fibroadipose tissue fragments, 3.0 x 2.5 x 1.0 cm in aggregate. A salivary gland is identified, 4.5 x 3.0 x 1.5 cm. Attached to the salivary gland, there is a red-tan lymph node, 1.5 cm in greatest dimension. There is an ovoid-shaped, white-tan solid mass, 4.5 x 4.0 x 3.0 cm. The mass is located 3.0 cm distal to the salivary gland. Thirty two lymph nodes are dissected, ranging from 0.2 cm to 2.0 cm in greatest dimension. Sections made through the salivary gland reveal an unremarkable yellow-gray, lobulated salivary gland parenchyma. The specimen is submitted in twenty seven cassettes, as follows:

Cassette #1-3:	Representative sections from the largest mass (level IIA, as per surgeon)
Cassette #4:	Lymph node adjacent to salivary gland, bisected and in toto
Cassette #5&6:	One lymph node bisected
Cassette #7&8:	One lymph node bisected
Cassette #9-22:	One lymph node bisected per cassette
Cassette #23-25:	Five lymph nodes in toto per cassette
Cassette #26&27:	Representative sections from salivary gland

- H. Received in formalin and labeled "Level IIB lymph node" is an irregular-shaped, yellow-tan fibroadipose tissue fragment, 3.5 x 2.5 x 1.8 cm. Examination of the specimen reveals six lymph nodes, ranging from 0.2 cm to 0.8 cm in greatest dimension. Lymph nodes are submitted in toto as follows:

Cassette #1:	One lymph node bisected
Cassette #2:	Three possible lymph nodes in toto
Cassette #3&4:	One lymph node bisected per cassette

- I. Received in formalin and labeled "Level VB lymph nodes" are multiple and irregular-shaped, yellow-tan fibroadipose tissue fragments, 3.5 x 3.5 x 2.0 cm. Four lymph nodes are dissected, ranging from 0.2 cm to 0.8 cm in greatest dimension. Lymph nodes are submitted in toto as follows:

Cassette #1&2:	One lymph node bisected, per cassette
Cassette #3:	Two lymph nodes in toto

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 6 of 6]
(Continued)

GROSS DESCRIPTION: (Continued)

OPERATING ROOM CONSULT (FS-CYT)

AFS: Negative for carcinoma.

BFS: Negative for carcinoma.

CFS: Negative for carcinoma.

DFS: Negative for carcinoma.

EFS: Negative for carcinoma.

Signed (Signature on file)

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [redacted]
return the report to us by mail.

Source: NCI Genomic Data Commons file 30b69224-9ccd-4f9d-bbe3-f0ddacb6ed7a (TCGA-IQ-A61I.0968C155-475B-49DA-B458-B36AAE2DEA5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).